Somatic mutation profile of tumor specimen ALCH-AE2Q-TTP1-A (aliquot ALCH-AE2Q-TTP1-A-1-0-D-A604-36) from ALCHEMIST case ALCH-AE2Q, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,015 days).
Specimen ALCH-AE2Q-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63b820b8-601f-4882-afc0-36ab28127162.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE2Q-NB1-A (Blood Derived Normal), aliquot ALCH-AE2Q-NB1-A-1-0-D-A604-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03b51237-e8d1-4747-b349-4502e4324ea0

The open-access MAF lists 253 somatic variants for this specimen: 178 protein-altering or splice-affecting, 45 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 159, Silent 45, Nonsense Mutation 13, Intron 12, RNA 7, 5'UTR 5, Splice Region 3, Splice Site 3, 3'UTR 3, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SALL1 | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 43/393 reads (11%) | catalogued as rs104894535, CM981786, CM991124; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.1293G>C p.L431F | Missense Mutation (SNP) | VAF 36/346 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.146); catalogued as rs1409077668, COSV70033566; called by muse, mutect2, varscan2
- ACAN | c.6482C>A p.A2161E | Missense Mutation (SNP) | VAF 62/634 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.829); catalogued as COSV61356917; called by muse, mutect2
- ADAMTS8 | c.2037C>A p.C679* | Nonsense Mutation (SNP) | VAF 26/319 reads (8%) | catalogued as COSV57290891; called by muse, mutect2
- ADAMTS8 | c.1915G>A p.E639K | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as rs775536904, COSV57291111; called by muse, mutect2
- ADGRG4 | c.3791C>A p.S1264Y | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV99796267; called by muse, varscan2
- ANKRD11 | c.2539G>T p.D847Y | Missense Mutation (SNP) | VAF 83/547 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56356955; called by muse, mutect2, varscan2
- ARID1A | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV61387263, COSV61391621; called by muse, varscan2
- B3GAT1 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV56995030; called by muse, mutect2
- BRPF1 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1434715999; called by muse, mutect2
- BSN | c.3940C>T p.P1314S | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56530133; called by muse, mutect2, varscan2
- C1orf54 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as rs782516643, COSV51743235; called by muse, mutect2, varscan2
- CALCRL | c.1077G>C p.K359N | Missense Mutation (SNP) | VAF 69/641 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV101130917, COSV101131009; called by muse, mutect2, varscan2
- CCDC62 | c.977+1G>C p.X326_splice | Splice Site (SNP) | VAF 70/325 reads (22%) | catalogued as rs771967288, COSV53434837; called by muse, mutect2, varscan2
- CDKN2A | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 71/502 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs11552823, CM080133, COSV58683884, COSV58697231, COSV58717232; called by muse, mutect2, varscan2
- CHRM2 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 14/181 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as COSV100280623; called by muse, mutect2
- COL22A1 | c.493G>T p.A165S | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV57355936; called by muse, mutect2
- COL6A1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.006); catalogued as rs1461577118; called by muse, mutect2, varscan2
- CPZ | c.718G>A p.E240K (on ENST00000360986 / NM_001014447.3; = p.E229K on NM_003652.3) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs751651131; called by muse, mutect2
- DCX | c.587G>T p.R196L | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs56030372, CM013361, COSV57566600; ClinVar: uncertain significance; called by muse, varscan2
- DDRGK1 | c.412G>C p.E138Q | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.784); catalogued as COSV63226995; called by muse, mutect2
- DHX9 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 37/442 reads (8%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.908); catalogued as rs1341615996; called by muse, mutect2
- DLC1 | c.1065G>A p.M355I | Missense Mutation (SNP) | VAF 34/263 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV52321300, COSV99365068; called by muse, mutect2, varscan2
- DNMT3A | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 56/371 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs951361433, CM144155; called by muse, mutect2, varscan2
- DNPEP | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 9/201 reads (4%) | SIFT tolerated (0.52); PolyPhen benign (0.105); catalogued as rs1374325564; called by muse, mutect2
- DSEL | c.2843A>G p.H948R | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs1453543314; called by muse, mutect2, varscan2
- EPGN | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 25/369 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs779175703; called by muse, mutect2
- FAM131B | c.847G>C p.E283Q | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.02); catalogued as COSV58374530; called by muse, mutect2, varscan2
- FAT3 | c.7156G>A p.D2386N | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs528105780; called by muse, mutect2
- FLG | c.7201C>A p.R2401S | Missense Mutation (SNP) | VAF 42/720 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs553468192, COSV64243028; called by muse, mutect2
- FLG | c.422C>A p.S141Y | Missense Mutation (SNP) | VAF 111/1152 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100910658, COSV64249847; called by muse, mutect2
- GALNT17 | c.799C>T p.R267W | Missense Mutation (SNP) | VAF 34/414 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs762495552, COSV61190791; called by muse, mutect2
- GFAP | c.1128-3C>T | Splice Region (SNP) | VAF 17/144 reads (12%) | catalogued as rs1176683819; called by muse, mutect2, varscan2
- GIMAP1 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.132); catalogued as rs1373463897, COSV100212241; called by muse, mutect2, varscan2
- GPA33 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs373880766; called by muse, mutect2
- HDLBP | c.3269A>G p.D1090G | Missense Mutation (SNP) | VAF 28/280 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as COSV60492264; called by muse, mutect2, varscan2
- HECW2 | c.2764G>A p.V922M | Missense Mutation (SNP) | VAF 36/203 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.738); catalogued as rs144884935; called by muse, mutect2, varscan2
- HMGXB4 | c.634C>G p.Q212E | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV53335448; called by muse, mutect2, varscan2
- HNRNPA1 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 33/561 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV52937419, COSV52938449; called by muse, mutect2
- IFNB1 | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.633); catalogued as rs1021655360; called by muse, mutect2, varscan2
- ILDR2 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV54829134; called by muse, mutect2, varscan2
- KCNC2 | c.402C>A p.F134L | Missense Mutation (SNP) | VAF 93/455 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV54382525; called by muse, mutect2, varscan2
- KCTD8 | c.1381C>G p.R461G | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.698); catalogued as COSV63586384; called by muse, varscan2
- KIR3DL1 | c.1318G>C p.V440L | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV58491991; called by muse, mutect2
- KRT17 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs1309344989; called by muse, mutect2
- LAIR1 | c.656G>T p.R219M | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV100479840; called by muse, mutect2
- MRPL9 | c.486G>A p.A162= | Splice Region (SNP) | VAF 51/423 reads (12%) | catalogued as rs762267979, COSV58617756; called by muse, mutect2, varscan2
- NLGN2 | c.2032G>T p.V678F | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57209659; called by muse, mutect2, varscan2
- NLRC5 | c.3208G>C p.E1070Q | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99346648; called by muse, mutect2, varscan2
- NTRK3 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV58149545; called by muse, mutect2
- NXPE3 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 44/464 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.341); catalogued as rs745327151; called by muse, mutect2
- OR6P1 | c.67C>T p.L23F | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1232919836, COSV58108516; called by muse, mutect2
- OSBPL1A | c.2504G>A p.R835Q (on ENST00000319481 / NM_080597.4; = p.R322Q on NM_018030.4) | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.532); catalogued as rs754651669, COSV60205997; called by muse, mutect2, varscan2
- PAK1IP1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV52584469, COSV99468416, COSV99468494; called by muse, mutect2
- PCDHB13 | c.2125G>A p.V709M | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as rs1554288152; called by muse, mutect2
- PCDHGA1 | c.1575C>A p.F525L | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.044); catalogued as COSV100966162; called by muse, mutect2, varscan2
- PDZRN4 | c.3062C>G p.P1021R (on ENST00000402685 / NM_001164595.2; = p.P763R on NM_013377.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54216958; called by muse, mutect2, varscan2
- PLXNA2 | c.4438G>A p.E1480K | Missense Mutation (SNP) | VAF 24/284 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1269275813, COSV65437873; called by muse, mutect2
- PRRG3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.7); catalogued as rs1176822976; called by muse, varscan2
- RAB40B | c.677C>G p.S226W | Missense Mutation (SNP) | VAF 41/344 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs1464517236, COSV53915617; called by muse, mutect2, varscan2
- RIT1 | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 51/419 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs948974325; called by muse, mutect2, varscan2
- RNF213 | c.14935C>G p.L4979V | Missense Mutation (SNP) | VAF 61/565 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60407587; called by muse, mutect2, varscan2
- SCG2 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs974275475; called by muse, varscan2
- SFSWAP | c.2038C>G p.Q680E | Missense Mutation (SNP) | VAF 30/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV55525912; called by muse, mutect2
- SLC12A7 | c.513G>C p.M171I | Missense Mutation (SNP) | VAF 22/430 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.85); catalogued as rs1365555968; called by muse, mutect2
- STIM2 | c.953G>A p.R318H | Missense Mutation (SNP) | VAF 38/436 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.572); catalogued as rs756946958; called by muse, mutect2
- TMEM200A | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1259176010; called by muse, mutect2
- TRPV4 | c.2359C>A p.H787N | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.272); catalogued as COSV55683256, COSV55683974; called by muse, mutect2
- VWF | c.5822G>T p.G1941V | Missense Mutation (SNP) | VAF 78/344 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1180283088; called by muse, mutect2, varscan2
- WBP2 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1056277129; called by muse, mutect2
- WNK4 | c.3154G>C p.E1052Q | Missense Mutation (SNP) | VAF 40/553 reads (7%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.767); catalogued as COSV99891216; called by muse, mutect2
- XDH | c.2818G>A p.E940K | Missense Mutation (SNP) | VAF 76/588 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.271); catalogued as rs761942456; called by muse, mutect2, varscan2
- ZFYVE19 | c.799G>A p.D267N (on ENST00000355341 / NM_001077268.2; = p.D257N on NM_032850.5) | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.536); catalogued as rs1351648333; called by muse, mutect2
- ZHX1 | c.2363A>G p.Y788C | Missense Mutation (SNP) | VAF 66/372 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1563808385; called by muse, mutect2, varscan2
- ZNF208 | c.1105T>A p.Y369N | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370096318; called by muse, mutect2, varscan2
- ZNF254 | c.1508C>G p.S503* | Nonsense Mutation (SNP) | VAF 28/400 reads (7%) | catalogued as rs753170366, COSV100741694; called by muse, mutect2
- ZNF469 | c.3236G>A p.R1079Q (on ENST00000437464; = p.R1107Q on NM_001367624.2) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.043); catalogued as rs281865148; ClinVar: benign; called by muse, mutect2, varscan2
- ZNF571 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.806); catalogued as rs373799629; called by muse, mutect2, varscan2
- ZNF808 | c.1357A>G p.K453E | Missense Mutation (SNP) | VAF 46/297 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1419309854; called by muse, mutect2, varscan2
- ZSWIM2 | c.243-1G>T p.X81_splice | Splice Site (SNP) | VAF 18/286 reads (6%) | catalogued as COSV54574528, COSV54577057, COSV54579018; called by muse, mutect2
- ABCA3 | c.1310T>A p.L437H | Missense Mutation (SNP) | VAF 49/430 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ABHD13 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 29/555 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2
- AKAP8L | c.1660G>C p.E554Q | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2
- ALDH18A1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- APC | c.2468C>G p.S823* | Nonsense Mutation (SNP) | VAF 44/474 reads (9%) | called by muse, mutect2
- ASAP3 | c.1258G>T p.E420* | Nonsense Mutation (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- AVPR2 | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRIP1 | c.1936-1G>T p.X646_splice | Splice Site (SNP) | VAF 48/542 reads (9%) | called by muse, mutect2
- CC2D1B | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CCDC33 | c.2209T>A p.S737T | Missense Mutation (SNP) | VAF 11/306 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- CCDC39 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 19/462 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- CD1B | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 29/217 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CENPW | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 49/472 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CERT1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); called by muse, mutect2
- CFAP61 | c.326T>A p.V109E | Missense Mutation (SNP) | VAF 56/598 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CIT | c.4636C>T p.P1546S | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.063); called by muse, mutect2
- COL23A1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CPB2 | c.888G>C p.L296F | Missense Mutation (SNP) | VAF 43/567 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- DENND1B | c.441G>T p.L147F | Missense Mutation (SNP) | VAF 34/424 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2
- DFFB | c.992A>G p.K331R | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); called by muse, mutect2
- DRD5 | c.411C>A p.D137E | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); called by muse, mutect2
- EIF3M | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 18/283 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ELMO2 | c.304G>C p.D102H | Missense Mutation (SNP) | VAF 20/313 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.289); called by muse, mutect2
- EPG5 | c.4516C>T p.P1506S | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); called by muse, mutect2
- ERCC6L2 | c.4450G>A p.E1484K | Missense Mutation (SNP) | VAF 18/325 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- EVC | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 38/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- EXT1 | c.1115T>C p.I372T | Missense Mutation (SNP) | VAF 31/625 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- FANCI | c.2992C>A p.P998T (on ENST00000310775 / NM_001376911.1; = p.P938T on NM_018193.3) | Missense Mutation (SNP) | VAF 46/744 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2
- FCRL4 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 15/321 reads (5%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.92); called by muse, mutect2
- FGF23 | c.77C>G p.P26R | Missense Mutation (SNP) | VAF 13/350 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- FRMPD4 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.218); called by muse, mutect2
- GIMAP2 | c.140C>G p.A47G | Missense Mutation (SNP) | VAF 82/716 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- GK2 | c.558G>C p.L186F | Missense Mutation (SNP) | VAF 21/275 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.853); called by muse, mutect2
- GRIA4 | c.948G>C p.R316S | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.159); called by muse, mutect2
- HEPHL1 | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.026); called by muse, mutect2
- HMGXB4 | c.370T>C p.S124P | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- HMGXB4 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- IMPG1 | c.1955C>A p.A652D | Missense Mutation (SNP) | VAF 84/629 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INTS11 | c.896T>G p.M299R | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2
- IQGAP3 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); called by muse, mutect2
- ITGA11 | c.3525G>C p.R1175S | Missense Mutation (SNP) | VAF 32/299 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- KCNK18 | c.517A>C p.T173P | Missense Mutation (SNP) | VAF 81/384 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCTD8 | c.539G>T p.R180L | Missense Mutation (SNP) | VAF 28/227 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAIR1 | c.657G>T p.R219S | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.98); called by muse, mutect2
- LCT | c.3815C>A p.T1272N | Missense Mutation (SNP) | VAF 44/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LHX8 | c.347A>T p.Y116F | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.989); called by muse, mutect2
- LIPN | c.518C>A p.S173* | Nonsense Mutation (SNP) | VAF 85/427 reads (20%) | called by muse, mutect2, varscan2
- LRP5 | c.3260A>G p.Q1087R | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.571); called by muse, mutect2
- LRRC37B | c.1906T>A p.C636S | Missense Mutation (SNP) | VAF 32/405 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.297); called by muse, mutect2
- LRRTM1 | c.904T>A p.S302T | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.671); called by muse, mutect2
- LTBP2 | c.1251G>T p.W417C | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LTBP2 | c.1250G>T p.W417L | Missense Mutation (SNP) | VAF 24/393 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAP2K1 | c.412G>T p.E138* | Nonsense Mutation (SNP) | VAF 40/600 reads (7%) | called by muse, mutect2
- MBD5 | c.197G>C p.C66S | Missense Mutation (SNP) | VAF 84/651 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MGAT4C | c.984T>A p.D328E | Missense Mutation (SNP) | VAF 12/231 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.078); called by muse, mutect2
- MICU1 | c.1226C>G p.S409* (on ENST00000361114 / NM_001195518.2; = p.S415* on NM_006077.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/294 reads (11%) | called by muse, mutect2, varscan2
- MXRA7 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | PolyPhen benign (0.202); called by muse, mutect2, varscan2
- NBAS | c.1072C>G p.Q358E | Missense Mutation (SNP) | VAF 96/726 reads (13%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- NCOR2 | c.7102C>G p.L2368V | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.619); called by muse, mutect2
- NDUFAF3 | c.104C>G p.S35W | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- NSMF | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 54/704 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- NUP54 | c.924C>G p.I308M | Missense Mutation (SNP) | VAF 26/367 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2
- NYNRIN | c.2619G>C p.K873N | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OBSL1 | c.3077G>T p.G1026V | Missense Mutation (SNP) | VAF 48/385 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OGA | c.1826C>G p.S609* | Nonsense Mutation (SNP) | VAF 30/254 reads (12%) | called by muse, mutect2, varscan2
- OR11A1 | c.391C>T p.L131F | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PBX1 | c.1186C>G p.P396A | Missense Mutation (SNP) | VAF 37/520 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2
- PCDHGA2 | c.52T>C p.F18L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- PPP1R9A | c.2896G>A p.D966N | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- PSME3 | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 24/611 reads (4%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.952); called by muse, mutect2
- PTDSS2 | c.821A>T p.K274M | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); called by muse, mutect2
- PTEN | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
- RFXAP | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 37/567 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2
- RRNAD1 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 34/456 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- RTL3 | c.506A>T p.E169V | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RUNX3 | c.484C>A p.Q162K | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SCN3A | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 63/760 reads (8%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.987); called by muse, mutect2
- SLC10A6 | c.189G>T p.R63S | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- SLC46A3 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- SMARCAL1 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 28/620 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2
- SNX19 | c.1003G>T p.A335S | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.295); called by muse, mutect2
- SPEG | c.2203C>A p.P735T | Missense Mutation (SNP) | VAF 31/240 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPON2 | c.850T>G p.S284A | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2
- SPTA1 | c.1964C>G p.S655C | Missense Mutation (SNP) | VAF 60/623 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- ST8SIA3 | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 73/718 reads (10%) | PolyPhen benign (0.021); called by muse, mutect2
- TIGD1 | c.1041G>C p.L347F | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2
- TMEM225B | c.130G>T p.E44* | Nonsense Mutation (SNP) | VAF 54/672 reads (8%) | called by muse, mutect2
- TNKS2 | c.1393C>T p.Q465* | Nonsense Mutation (SNP) | VAF 16/284 reads (6%) | called by muse, mutect2
- TOPAZ1 | c.3807G>T p.M1269I | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.015); called by muse, mutect2
- TRIP11 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 25/293 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- TRPC6 | c.2006C>T p.T669I | Missense Mutation (SNP) | VAF 11/280 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.85204A>C p.T28402P (on ENST00000591111; = p.T20978P on NM_003319.4) | Missense Mutation (SNP) | VAF 18/309 reads (6%) | PolyPhen possibly damaging (0.79); called by muse, mutect2
- TTN | c.27963C>A p.F9321L (on ENST00000591111; = p.F8394L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/512 reads (11%) | PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.4646-7C>G | Splice Region (SNP) | VAF 85/779 reads (11%) | called by muse, mutect2, varscan2
- UTP15 | c.424G>A p.D142N | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- YAP1 | c.942G>C p.E314D (on ENST00000282441 / NM_001130145.3; = p.E276D on NM_006106.5) | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- ZNF431 | c.1168C>A p.H390N | Missense Mutation (SNP) | VAF 17/162 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF831 | c.4874A>T p.D1625V | Missense Mutation (SNP) | VAF 52/375 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.243); called by muse, varscan2
- ABCF2 | c.342T>C p.Y114= | Silent (SNP) | VAF 66/626 reads (11%) | catalogued as rs1408504164; called by muse, mutect2, varscan2
- ADAMTS12 | c.2937C>T p.C979= | Silent (SNP) | VAF 40/585 reads (7%) | catalogued as rs944632546, COSV61265817; called by muse, mutect2
- ARAP1 | c.2685C>T p.F895= (on ENST00000393609 / NM_001040118.2; = p.F650= on NM_015242.4) | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV100502095; called by muse, mutect2, varscan2
- BDP1 | c.1740G>A p.V580= | Silent (SNP) | VAF 20/314 reads (6%) | called by muse, mutect2
- CFAP99 | c.825C>T p.F275= | Silent (SNP) | VAF 20/328 reads (6%) | called by muse, mutect2
- CHSY3 | c.696C>T p.S232= | Silent (SNP) | VAF 40/348 reads (11%) | catalogued as rs774477266; called by muse, mutect2, varscan2
- CR1L | c.1698C>T p.F566= | Silent (SNP) | VAF 10/213 reads (5%) | called by muse, mutect2
- CRNN | c.1191G>A p.E397= | Silent (SNP) | VAF 51/572 reads (9%) | catalogued as rs1263846246; called by muse, mutect2
- EYS | c.927C>T p.C309= | Silent (SNP) | VAF 46/440 reads (10%) | called by muse, varscan2
- GNAS | c.402C>T p.F134= | Silent (SNP) | VAF 33/225 reads (15%) | catalogued as rs771418632, COSV100005720; called by muse, mutect2, varscan2
- HCN1 | c.1806G>C p.L602= | Silent (SNP) | VAF 56/583 reads (10%) | called by muse, mutect2
- IGKV4-1 | c.108C>G p.G36= | Silent (SNP) | VAF 17/171 reads (10%) | called by muse, mutect2
- ISCA2 | c.63G>A p.P21= | Silent (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- LHX8 | c.345T>C p.C115= | Silent (SNP) | VAF 23/591 reads (4%) | called by muse, mutect2
- MAN2B2 | c.486A>G p.L162= | Silent (SNP) | VAF 28/245 reads (11%) | catalogued as rs755558768; called by muse, mutect2, varscan2
- MED13 | c.5730C>A p.L1910= | Silent (SNP) | VAF 16/333 reads (5%) | catalogued as COSV67267501; called by muse, mutect2
- MS4A14 | c.465C>T p.F155= | Silent (SNP) | VAF 22/574 reads (4%) | called by muse, mutect2
- MUC16 | c.33603C>A p.S11201= | Silent (SNP) | VAF 32/206 reads (16%) | called by muse, mutect2, varscan2
- MZF1 | c.549G>A p.V183= | Silent (SNP) | VAF 21/143 reads (15%) | catalogued as rs764830623, COSV53043214; called by muse, mutect2, varscan2
- NDUFAF3 | c.15C>G p.L5= | Silent (SNP) | VAF 72/360 reads (20%) | called by muse, mutect2, varscan2
- OLFM3 | c.960G>T p.G320= (on ENST00000338858 / NM_001288821.1; = p.G300= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/454 reads (13%) | catalogued as COSV58798430; called by muse, mutect2, varscan2
- PITPNM3 | c.715C>A p.R239= | Silent (SNP) | VAF 56/472 reads (12%) | called by muse, mutect2, varscan2
- PWWP3A | c.1446C>T p.F482= (on ENST00000627377; = p.F481= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 38/267 reads (14%) | called by muse, mutect2, varscan2
- RAG1 | c.396T>A p.P132= | Silent (SNP) | VAF 39/515 reads (8%) | called by muse, mutect2
- RIPOR2 | c.708G>A p.L236= | Silent (SNP) | VAF 24/344 reads (7%) | catalogued as rs1267990992; called by muse, mutect2
- RNF213 | c.15387C>T p.F5129= | Silent (SNP) | VAF 74/638 reads (12%) | called by muse, varscan2
- RPGRIP1 | c.2967G>A p.G989= | Silent (SNP) | VAF 24/308 reads (8%) | called by muse, mutect2
- SALL1 | c.2499T>C p.P833= | Silent (SNP) | VAF 51/408 reads (13%) | called by muse, mutect2, varscan2
- SCAND1 | c.228C>G p.L76= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as rs540385747; called by mutect2, varscan2
- SCGN | c.111C>T p.L37= | Silent (SNP) | VAF 12/319 reads (4%) | called by muse, mutect2
- SDCCAG8 | c.1701G>C p.L567= | Silent (SNP) | VAF 22/460 reads (5%) | called by muse, mutect2
- SETDB1 | c.1617C>G p.P539= | Silent (SNP) | VAF 5/40 reads (13%) | called by mutect2, varscan2
- SLC4A3 | c.645C>T p.L215= | Silent (SNP) | VAF 24/182 reads (13%) | catalogued as rs559059275; called by muse, mutect2, varscan2
- SLFN13 | c.1422C>A p.T474= | Silent (SNP) | VAF 22/279 reads (8%) | called by muse, mutect2
- SMARCAL1 | c.1806C>T p.F602= | Silent (SNP) | VAF 86/981 reads (9%) | called by muse, mutect2
- SPHKAP | c.111G>A p.P37= | Silent (SNP) | VAF 50/447 reads (11%) | catalogued as rs201911651, COSV60878469; called by muse, mutect2, varscan2
- SUZ12 | c.2133A>T p.G711= | Silent (SNP) | VAF 19/218 reads (9%) | called by muse, mutect2
- THRB | c.264G>A p.T88= | Silent (SNP) | VAF 31/285 reads (11%) | catalogued as rs768009297; called by muse, mutect2, varscan2
- TMEM132E | c.2298C>T p.G766= (on ENST00000321639; = p.G856= on NM_001304438.2) | Silent (SNP) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- TPO | c.438C>T p.C146= | Silent (SNP) | VAF 32/823 reads (4%) | called by muse, mutect2
- VILL | c.261G>T p.L87= | Silent (SNP) | VAF 42/243 reads (17%) | catalogued as rs370182077; called by muse, mutect2, varscan2
- ZBTB8OS | c.351C>T p.F117= | Silent (SNP) | VAF 27/261 reads (10%) | catalogued as COSV59385238; called by muse, mutect2, varscan2
- ZFHX4 | c.10731T>A p.S3577= | Silent (SNP) | VAF 23/460 reads (5%) | called by muse, mutect2
- ZNF532 | c.438G>C p.V146= | Silent (SNP) | VAF 21/422 reads (5%) | called by muse, mutect2
- ZSCAN10 | c.1110C>G p.T370= (on ENST00000252463; = p.T425= on NM_032805.3) | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as rs764799478; called by muse, mutect2, varscan2
- ABI3BP | c.1577-7710G>T | Intron (SNP) | VAF 24/320 reads (8%) | called by muse, mutect2
- AC020637.1 | n.801-444G>T | Intron (SNP) | VAF 14/213 reads (7%) | called by muse, mutect2
- AKR1C1 | c.570+735G>C | Intron (SNP) | VAF 37/355 reads (10%) | called by muse, mutect2, varscan2
- DCHS2 | n.8576C>A | RNA (SNP) | VAF 17/170 reads (10%) | catalogued as COSV61775379; called by muse, mutect2, varscan2
- DNAJC19 | c.*633C>T | 3'UTR (SNP) | VAF 34/250 reads (14%) | called by muse, mutect2, varscan2
- DOCK10 | c.124-15272A>T | Intron (SNP) | VAF 23/216 reads (11%) | called by muse, mutect2, varscan2
- EEF1G | c.-4C>T | 5'UTR (SNP) | VAF 47/424 reads (11%) | called by muse, mutect2, varscan2
- ERBB2 | c.1514-38C>T | Intron (SNP) | VAF 10/60 reads (17%) | catalogued as rs1261475108; called by muse, varscan2
- ETV5 | c.-75+425G>C | Intron (SNP) | VAF 8/126 reads (6%) | called by muse, mutect2
- GSG1L | c.551-5516C>A | Intron (SNP) | VAF 39/308 reads (13%) | called by muse, mutect2, varscan2
- GVINP1 | n.3545G>A | RNA (SNP) | VAF 30/326 reads (9%) | catalogued as rs1488835213; called by muse, mutect2
- HDAC8 | chrX:72572844 G>A | 5'Flank (SNP) | VAF 28/223 reads (13%) | called by muse, mutect2, varscan2
- IFT172 | c.-18G>A | 5'UTR (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- KIAA2012 | c.369+1835C>A | Intron (SNP) | VAF 40/381 reads (10%) | called by muse, mutect2
- LINC02817 | n.244T>G | RNA (SNP) | VAF 26/254 reads (10%) | called by muse, mutect2
- MATR3 | c.*501G>A | 3'UTR (SNP) | VAF 77/566 reads (14%) | called by muse, mutect2, varscan2
- MORF4 | n.335G>C | RNA (SNP) | VAF 40/418 reads (10%) | called by muse, mutect2
- MSC | c.534+42G>A | Intron (SNP) | VAF 10/92 reads (11%) | called by muse, mutect2, varscan2
- NUP210P1 | n.479C>A | RNA (SNP) | VAF 51/411 reads (12%) | catalogued as rs1243318004; called by muse, mutect2, varscan2
- OSBPL9 | c.582+17C>G | Intron (SNP) | VAF 20/278 reads (7%) | called by muse, mutect2
- RBIS | c.114+63G>A | Intron (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- RFESD | c.-56G>A | 5'UTR (SNP) | VAF 15/213 reads (7%) | called by muse, mutect2
- SLC34A2 | c.*21G>T | 3'UTR (SNP) | VAF 21/360 reads (6%) | called by muse, mutect2
- SLC35C1 | c.-24G>T | 5'UTR (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- SRSF7 | c.386+233G>C | Intron (SNP) | VAF 63/389 reads (16%) | called by muse, mutect2, varscan2
- SSPOP | n.9581C>T | RNA (SNP) | VAF 20/148 reads (14%) | catalogued as rs760400436, COSV65138328; called by muse, varscan2
- SYCP2L | c.-14G>A | 5'UTR (SNP) | VAF 29/221 reads (13%) | catalogued as COSV99304431; called by muse, mutect2, varscan2
- TMA16 | chr4:163494544 C>T | 5'Flank (SNP) | VAF 11/192 reads (6%) | catalogued as rs1484546491; called by muse, mutect2
- TTC41P | n.254C>T | RNA (SNP) | VAF 28/444 reads (6%) | catalogued as rs1322132461; called by muse, mutect2
- Y_RNA | chr7:75515801 T>C | 5'Flank (SNP) | VAF 30/274 reads (11%) | called by muse, mutect2, varscan2
